Somatic mutation profile of tumor specimen TCGA-BK-A13C-01A (aliquot TCGA-BK-A13C-01A-11D-A122-09) from TCGA case TCGA-BK-A13C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 47.4 years (17,317 days).
Specimen TCGA-BK-A13C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5af7877-a306-41ed-ae85-655d568aeed8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A13C-10A (Blood Derived Normal), aliquot TCGA-BK-A13C-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9497700a-b7d7-4797-bb17-cf81d9669716

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 177/400 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- PTEN | c.802-1G>A p.X268_splice | Splice Site (SNP) | VAF 93/98 reads (95%) | hotspot (GDC flag); catalogued as rs1257124719, COSV100909782, COSV64290925, COSV64293353; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 21/36 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- ADCY3 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779224629, COSV53164883; called by muse, mutect2, varscan2
- AGPAT5 | c.1026G>T p.R342S | Missense Mutation (SNP) | VAF 145/315 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV53445787; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 22/57 reads (39%) | catalogued as rs758608743; called by mutect2, varscan2
- ARVCF | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs1381433990, COSV52889213; called by muse, mutect2, varscan2
- ATG9A | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV54693450; called by muse, mutect2, varscan2
- AXL | c.1135-1G>C p.X379_splice | Splice Site (SNP) | VAF 24/131 reads (18%) | catalogued as COSV56564435; called by muse, mutect2, varscan2
- C9orf152 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV68762707; called by muse, mutect2, varscan2
- CD1C | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 279/383 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV63805793; called by muse, mutect2, varscan2
- CHD4 | c.3436A>G p.R1146G (on ENST00000357008 / NM_001363606.2; = p.R1159G on NM_001273.5) | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58895872; called by muse, mutect2, varscan2
- CNOT1 | c.1613T>C p.I538T | Missense Mutation (SNP) | VAF 157/344 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs201410669, COSV57765574; called by muse, mutect2, varscan2
- COL12A1 | c.8236G>A p.V2746I | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as rs374979813; called by muse, mutect2, varscan2
- ENPP1 | c.1580G>T p.R527M | Missense Mutation (SNP) | VAF 119/327 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.56); catalogued as COSV62930495; called by muse, mutect2, varscan2
- FAM83H | c.3502G>A p.V1168M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369901205, COSV62027504; called by muse, mutect2, varscan2
- FAP | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs376781426, COSV51862159; called by muse, mutect2, varscan2
- GPR4 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1469399830, COSV59916303, COSV59916377; called by muse, mutect2, varscan2
- HNRNPH2 | c.1031del p.A344Vfs*18 | Frame Shift Del (DEL) | VAF 72/178 reads (40%) | catalogued as COSV57265694; called by mutect2, pindel, varscan2
- HTR3C | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs183919204, COSV59174440; called by muse, mutect2, varscan2
- HYI | c.569C>T p.T190M (on ENST00000372434 / NM_001330526.2; = p.T165M on NM_031207.6) | Missense Mutation (SNP) | VAF 143/320 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as rs201885225; called by muse, mutect2
- IGSF1 | c.2173C>A p.Q725K | Missense Mutation (SNP) | VAF 166/363 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV63836391; called by muse, mutect2, varscan2
- JAKMIP3 | c.1414T>A p.S472T | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV53820246; called by muse, varscan2
- KLK6 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs553226234, COSV100037844, COSV59564993; called by muse, mutect2, varscan2
- LCE2C | c.95G>T p.C32F | Missense Mutation (SNP) | VAF 225/958 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs1250342406, COSV64228286, COSV64228626; called by muse, mutect2, varscan2
- MAP7D2 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 176/420 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV65525818; called by muse, mutect2, varscan2
- MS4A1 | c.337-1G>T p.X113_splice | Splice Site (SNP) | VAF 85/165 reads (52%) | catalogued as COSV100619405, COSV61941753; called by muse, mutect2, varscan2
- MYH4 | c.5276C>G p.A1759G | Missense Mutation (SNP) | VAF 106/579 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1418977431, COSV55113323; called by muse, mutect2, varscan2
- MYH4 | c.1208G>T p.C403F | Missense Mutation (SNP) | VAF 116/246 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55113333; called by muse, mutect2, varscan2
- OTOGL | c.7046C>T p.T2349M (on ENST00000547103; = p.T2340M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747031736, COSV54013827; called by muse, mutect2, varscan2
- PGBD1 | c.2234T>C p.I745T | Missense Mutation (SNP) | VAF 126/254 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.407); catalogued as COSV52551555; called by muse, mutect2, varscan2
- PPAN | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs371648303, COSV99461153; called by muse, varscan2
- PPP1R3A | c.2843C>T p.T948M | Missense Mutation (SNP) | VAF 85/153 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs754703917, COSV52877557, COSV99493253; called by muse, mutect2, varscan2
- RAP2C | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 106/242 reads (44%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.756); catalogued as COSV61683162; called by muse, varscan2
- RIPK1 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs771573328, COSV52528129; called by muse, mutect2, varscan2
- SERTAD2 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 45/97 reads (46%) | catalogued as COSV57639706; called by muse, mutect2, varscan2
- TCF4 | c.940del p.A314Qfs*77 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as CD084987; called by mutect2, pindel, varscan2
- TENM3 | c.3848T>A p.L1283H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101305032; called by muse, mutect2
- WWC3 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1405713941, COSV66501778; called by muse, mutect2, varscan2
- ZNF2 | c.841G>T p.D281Y (on ENST00000611147 / NM_001291605.2; = p.D268Y on NM_021088.4) | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as rs774462962, COSV99728375; called by muse, mutect2, varscan2
- ABCC9 | c.2241G>A p.R747= | Silent (SNP) | VAF 65/154 reads (42%) | catalogued as COSV53963948, COSV53991305; called by muse, mutect2, varscan2
- GPR39 | c.1011G>A p.S337= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs1558870597, COSV61415842; called by muse, mutect2, varscan2
- MYBPC3 | c.1152C>G p.T384= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as rs775237084, COSV57022398, COSV57023784; called by muse, mutect2, varscan2
- MYH11 | c.1923C>T p.S641= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs530466304, COSV55544761; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHGB3 | c.1506G>A p.S502= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs370015318; called by muse, mutect2, varscan2
- RFLNB | c.27C>T p.P9= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs782560199, COSV61239135; called by muse, mutect2, varscan2
- RHOXF1 | c.264G>A p.P88= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs201599692, COSV54294231; called by muse, mutect2, varscan2
- THBS1 | c.1902C>T p.V634= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs1191302738, COSV52949913; called by muse, mutect2, varscan2
- TMCO4 | c.42G>A p.Q14= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV53869537; called by muse, mutect2, varscan2
- TMEM11 | c.252G>A p.T84= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs767169112, COSV58312893; called by muse, varscan2
- USP8 | c.1065T>C p.S355= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as COSV56162637; called by muse, mutect2, varscan2
- FAM98B | chr15:38484348 G>A | 3'Flank (SNP) | VAF 18/57 reads (32%) | catalogued as COSV60363884; called by muse, mutect2, varscan2
- PARGP1 | n.1336G>T | RNA (SNP) | VAF 190/450 reads (42%) | called by muse, mutect2, varscan2
